Surgical pathology report (de-identified scan), TCGA case TCGA-18-3407, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3407-01A (Primary Tumor).

[page 1 of 3]
TCGA-18-3407

Copath #:
Collected:
Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST2R UP Paratracheal
2. Lymph node: right low paratracheal ST4R
3. Lymph node: subcarinal ST7
4. Lymph node: left low paratracheal ST4L
5. Lymph node: INF pulm ligament ST9
- LUNG: LUL bronchial resection margin

DIAGNOSIS

1-5. ST2R upper paratracheal, right low paratracheal 4R, ST7 subcarinal, left low paratracheal 4L
and inferior pulmonary ligament ST9 lymph nodes - Negative for malignancy.

6. Left upper lobe

- a) Invasive moderately-differentiated squamous cell carcinoma, peripheral but with
no invasion into overlying visceral pleura, 4.0 cm maximum dimension
- b) Bronchial margin of resection - Negative for malignancy
- c) Lobar lymph nodes (2 examined) - Negative for malignancy
- d) Focal area of nonspecific pleuropulmonary fibrosis
- e) Pulmonary emphysema.

COMMENT

Examination of this material indicates apparent complete resection of a T2N0 squamous cell carcinoma.

CLINICAL HISTORY

Status: complete

[page 2 of 3]
Copath #:

Collected:

Resulted:

GROSS DESCRIPTION

1. The specimen container labelled with the patient's name and as "lymph node: ST2R upper paratracheal" consists of multiple pieces of dark nodal tissue the largest measuring 1.0 x 0.7 x 0.5 cm received fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

1A - frozen section embedded in toto (resubmitted)

2. The specimen container labelled with the patient's name and as "lymph node: right low paratracheal ST4R-QS" consists of multiple fragments of dark nodal tissue measuring in total 0.5 x 0.3 x 0.3 cm received fresh. This is examined in intraoperative consultation by frozen section performed on the entire specimen.

2A - frozen section embedded in toto (resubmitted).

3. The specimen container labelled with the patient's name and as "lymph node: subcarinal ST7" consists of multiple fragments of dark nodal tissue measuring in total 0.5 x 0.5 x 0.3 cm received fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

3A - frozen section embedded in toto (resubmitted).

4. The specimen container labelled with the patient's name and as "lymph node: left low paratracheal ST4L-QS" consists of fragments of dark nodal tissue in total measuring 0.5 x 0.2 x 0.2 cm received fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

4A - frozen section embedded in toto (resubmitted).

5. The specimen container labelled with the patient's name and as "lymph node: inferior pulmonary ligament ST9" consists of a piece of grey yellow nodal tissue measuring 1.0 x 0.8 x 0.5 cm received in 10% buffered formalin.

5A - submitted in toto.

6. The specimen container labelled with the patient's name and as "lung: left upper lobe bronchial resection margin-QS" consists of a left upper lobe of lung measuring 10.8 x 9.5 x 9.0 cm received fresh. This is examined at intraoperative consultation by frozen section performed on

[page 3 of 3]
Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

part of the specimen. On sectioning there is an anthracotic yellow to grey tan peripheral tumour noted measuring 4.0 cm in maximum dimension. There is also an area of fibrosis with pleural fibrosis noted also measuring 1.3 x 0.4 cm. The remainder of the specimen appears to be emphysematous and no other gross lesions are noted. Multiple lobar nodes were identified measuring from 0.5 up to 1.2 cm.

Sections are submitted as follows:

6A - frozen section, resection margin taken en face (resubmitted)

6B - two lobar nodes

6C - one lobar node

6D to 6F - representative sections of tumour in relation to normal lung parenchyma

6G and 6H - representative sections of tumour in relation to pleura

6I - one representative section of the area of fibrosis

6J and 6K - representative sections from apparently emphysematous lung

6L and 6M - representative sections from apparently normal lung parenchyma

Two pieces of tumour tissue and a piece oftissue are taken for tissue frozen.

QUICK SECTION

Frozen section diagnosis by [REDACTED] on frozen section blocks

1A to 4A - "Negative for malignancy".

Frozen section diagnosis by [REDACTED] on frozen section block

6A: "Negative for malignancy".

Source: NCI Genomic Data Commons file 6d2895ef-95b0-4d15-87e5-135472366d36 (TCGA-18-3407.C9B161D4-E3E2-43A9-8997-195DB2FCC1D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).